CCDI case PBBZDT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/c254fdc0-fc0d-4c54-89f5-90531cfc5a65

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 12.3 years (4,483 days).

Biospecimens (3 samples)
- Sample 0DL6RM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL6SG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DL6V2: Tissue type: Tumor; Specimen type: Solid Tissue.
